Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XO-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Pheochromocytoma, malignant
8700/3

Site @ Adrenal gland NOS
074.9

JW 4/3/13

Diagnosis:

Adrenal mass, left, adrenalectomy

Tumor histologic type: pheochromocytoma

Tumor size: 3.0 x 2.5 x 2.0 cm

Tumor gland weight: 17.6g

Specimen integrity: intact

Extent of invasion:

Extracapsular invasion: not identified

Vascular invasion: not identified

Surgical margins: Focally extends to cauterized parenchymal margin (A2)

Pass histologic grade: Total score 8 (of 20)

Large nests 2

High cellularity 2

Spindling 2

Nuclear pleomorphism 1

Nuclear hyperchromasia 1

Status of adrenal gland away from tumor: unremarkable cortex

Lymph nodes:

Number of lymph nodes involved: n/a

Number of lymph nodes examined: 0

AJCC TNM Stage: n/a

Clinical History:

year-old female with a 3 cm left adrenal mass, suspected pheochromocytoma.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left adrenal pheochromocytoma." It consists of a 17.6 gram, 5.4 x 3.0 x 2.5 cm adrenal gland and periadrenal fat. The

[page 2 of 2]
adrenal is inked blue. Serial sections reveal a 3.0 x 2.0 x 2.5 cm yellow/tan focally necrotic, primarily well demarcated soft mass arising from the adrenal. The residual adrenal gland is golden yellow. The mass grossly abuts the adrenal capsule (blue ink).

Block summary:

A1 - adrenal with adjacent mass

A2-A4 - Representative sections of mass

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

Sections show an adrenal medullary neoplasm with nested and diffuse architecture, with hypercellularity of high N:C ratio cells, with focal spindle cell cytology, with marked nuclear pleomorphism, with focally prominent nuclear hyperchromasia. By H & E alone, features are consistent with pheochromocytoma. No coagulative tumor cell necrosis, high mitotic activity, atypical mitotic figures, cellular monotony, extra-adrenal extension, or vascular invasion is noted. Neoplasm focally extends to inked surfaces in several blocks, and focally extends to cautery margin in block A2, which we interpret as surgical margin involvement. The Pass score is 8 of 20, with scores over 4 indicative of potentially aggressive behavior (metastatic potential).

Reviewer Initials	Case Reviewed:	2/19/13

Source: NCI Genomic Data Commons file 27579b8d-b00b-4cfd-84af-15fd585de8ed (TCGA-QT-A5XO.FA925844-32D7-4D5E-B42A-142CEA5F04BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).